Somatic mutation profile of tumor specimen TCGA-13-1500-01A (aliquot TCGA-13-1500-01A-01D-0472-01) from TCGA case TCGA-13-1500, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.7 years (26,172 days).
Specimen TCGA-13-1500-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 399dbd90-b27d-407a-9930-7f4c20a93a07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1500-10A (Blood Derived Normal), aliquot TCGA-13-1500-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74a617af-79b2-4531-9cd1-58110f76a833

The open-access MAF lists 79 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Frame Shift Ins 4, Frame Shift Del 2, Splice Site 2, Intron 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 205/381 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3836T>C p.L1279P | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100217653; called by muse, mutect2, varscan2
- AFF3 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100419595; called by muse, mutect2
- AGBL2 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 231/396 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100102045, COSV54093049; called by muse, mutect2, varscan2
- AMPD1 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 201/614 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100815198; called by muse, mutect2, varscan2
- AP1B1 | c.1537-1G>A p.X513_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100434774; called by muse, mutect2
- ARHGEF28 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs112237001, COSV99709960; called by muse, mutect2, varscan2
- BMP1 | c.1839dup p.N614Qfs*21 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | catalogued as rs758822270; called by mutect2, varscan2
- BMP8A | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100090228; called by muse, mutect2
- CACNA1A | c.5674G>C p.D1892H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV100803102; called by muse, mutect2
- CAPN1 | c.1918A>T p.M640L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV99658880; called by muse, mutect2, varscan2
- CDH18 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 98/364 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.81); catalogued as rs368942671, COSV56903027; called by muse, mutect2, varscan2
- CHD2 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 357/973 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765118718, COSV101245887; called by muse, mutect2, varscan2
- CNTNAP1 | c.3280C>G p.P1094A | Missense Mutation (SNP) | VAF 90/171 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99226915; called by muse, mutect2, varscan2
- COL22A1 | c.60T>A p.S20R | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57352132; called by muse, mutect2
- CYB5R1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768353653, COSV65917248; called by muse, mutect2, varscan2
- DAB2IP | c.1592T>C p.M531T (on ENST00000408936; = p.M503T on NM_032552.3) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99406242; called by muse, mutect2
- DHCR7 | c.26T>A p.I9N | Missense Mutation (SNP) | VAF 41/601 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100832098; called by muse, mutect2
- DISC1 | c.2426A>C p.Q809P | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100790755; called by muse, mutect2
- DNAH10 | c.2633T>A p.I878N (on ENST00000409039; = p.I817N on NM_207437.3) | Missense Mutation (SNP) | VAF 116/948 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101292575; called by muse, mutect2, varscan2
- DSCAML1 | c.6070G>A p.A2024T (on ENST00000321322; = p.A1964T on NM_020693.4) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as rs761872269, COSV100356985; called by muse, varscan2
- FAM155A | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1323179863, COSV65551187; called by muse, varscan2
- FBXO4 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1031536647, COSV99715270; called by muse, mutect2
- FLG | c.7555A>T p.N2519Y | Missense Mutation (SNP) | VAF 613/1472 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100912040; called by muse, mutect2, varscan2
- GIGYF2 | c.1802A>T p.H601L | Missense Mutation (SNP) | VAF 354/1065 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV101004587; called by muse, mutect2, varscan2
- GLB1L | c.56C>T p.T19M | Missense Mutation (SNP) | VAF 135/333 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1207499779, COSV55478366; called by muse, mutect2, varscan2
- HLX | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100854612; called by muse, mutect2
- IKZF4 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100009317; called by muse, mutect2, varscan2
- ITGAX | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV99192002; called by muse, mutect2
- KCND3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 113/469 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56185340; called by muse, mutect2, varscan2
- KIAA1328 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99695203; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 15/87 reads (17%) | catalogued as rs757410385; called by mutect2, varscan2
- MAP2K4 | c.1087-1G>T p.X363_splice | Splice Site (SNP) | VAF 29/348 reads (8%) | catalogued as COSV100796487, COSV62259084, COSV62260171; called by muse, mutect2
- MASTL | c.1372dup p.I458Nfs*5 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs780698479; called by mutect2, varscan2
- NBEAL1 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.045); catalogued as COSV101495771; called by muse, mutect2, varscan2
- NFASC | c.1507G>A p.A503T (on ENST00000339876 / NM_001378329.1; = p.A514T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/536 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs780692017, COSV58359304; called by muse, mutect2, varscan2
- NUCKS1 | c.306A>T p.K102N | Missense Mutation (SNP) | VAF 120/398 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100900793; called by muse, mutect2, varscan2
- OTX2 | c.800A>T p.K267M (on ENST00000408990 / NM_172337.3; = p.K275M on NM_021728.4) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100258073; called by muse, mutect2
- PARP8 | c.1837A>G p.T613A | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1042446264, COSV55860713, COSV99892590; called by muse, mutect2
- PCDHA13 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 20/700 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.034); catalogued as COSV56537515; called by muse, mutect2
- PCNT | c.3796G>T p.A1266S | Missense Mutation (SNP) | VAF 199/343 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100855983; called by muse, mutect2, varscan2
- PSG4 | c.1071G>T p.E357D | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99737738, COSV99737975; called by muse, mutect2
- RAG2 | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 154/258 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM081770, COSV100271476; called by muse, mutect2, varscan2
- RSC1A1 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 276/726 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1046502353, COSV60782152; called by muse, mutect2, varscan2
- SCEL | c.1598T>C p.V533A (on ENST00000349847 / NM_144777.3; = p.V513A on NM_003843.4) | Missense Mutation (SNP) | VAF 251/637 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs753108226, COSV100583172; called by muse, mutect2, varscan2
- SLC39A9 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 99/333 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs1333707360, COSV99220660; called by muse, mutect2, varscan2
- SP140 | c.1745C>G p.T582S | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as rs1559341248, COSV100613391, COSV100614017; called by muse, mutect2, varscan2
- SSRP1 | c.1547A>T p.K516M | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV99555100; called by muse, mutect2
- TET1 | c.1688C>A p.T563N | Missense Mutation (SNP) | VAF 62/752 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV101018819; called by muse, mutect2
- TMCO4 | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV99617457; called by muse, mutect2, varscan2
- TMEM182 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV101305413; called by muse, varscan2
- TRPC5 | c.2618A>G p.Q873R | Missense Mutation (SNP) | VAF 101/782 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.037); catalogued as COSV99462531; called by muse, mutect2, varscan2
- WDR35 | c.2627T>C p.V876A (on ENST00000345530 / NM_001006657.2; = p.V865A on NM_020779.4) | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99853471; called by muse, mutect2
- ZNF229 | c.1471T>C p.C491R | Missense Mutation (SNP) | VAF 80/647 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1161898111, COSV99350833; called by muse, mutect2, varscan2
- ABCA12 | c.3037_3040del p.H1013Tfs*31 (on ENST00000272895 / NM_173076.3; = p.H695Tfs*31 on NM_015657.3) | Frame Shift Del (DEL) | VAF 215/658 reads (33%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.1497A>G p.I499M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by mutect2, varscan2
- CISD1 | c.318dup p.E107Rfs*8 | Frame Shift Ins (INS) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- HDAC6 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SOCS4 | c.956_959del p.L319Sfs*42 | Frame Shift Del (DEL) | VAF 196/556 reads (35%) | called by pindel, varscan2
- ATP2B4 | c.3327G>T p.A1109= | Silent (SNP) | VAF 80/288 reads (28%) | catalogued as COSV100397994, COSV58177192; called by muse, mutect2, varscan2
- BCORL1 | c.1677G>A p.K559= | Silent (SNP) | VAF 79/250 reads (32%) | catalogued as COSV54408177, COSV99500706; called by muse, mutect2, varscan2
- CLN8 | c.606C>T p.H202= | Silent (SNP) | VAF 201/312 reads (64%) | catalogued as COSV100486110; called by muse, mutect2, varscan2
- COL22A1 | c.4752A>G p.Q1584= | Silent (SNP) | VAF 34/266 reads (13%) | catalogued as COSV100280489; called by muse, mutect2, varscan2
- DGKG | c.1899C>T p.H633= | Silent (SNP) | VAF 73/237 reads (31%) | catalogued as rs200349299, COSV99404223; called by muse, mutect2, varscan2
- FAM168A | c.12T>C p.V4= | Silent (SNP) | VAF 28/584 reads (5%) | catalogued as COSV99292261; called by muse, mutect2
- HIF1A | c.2250T>G p.L750= | Silent (SNP) | VAF 22/488 reads (5%) | catalogued as COSV100049198; called by muse, mutect2
- HIP1R | c.1335G>A p.A445= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs778578403, COSV99459217; called by muse, mutect2, varscan2
- KDM3A | c.1923A>C p.S641= | Silent (SNP) | VAF 64/1123 reads (6%) | catalogued as COSV100460889; called by muse, mutect2
- TERF2IP | c.729C>A p.I243= | Silent (SNP) | VAF 9/165 reads (5%) | catalogued as COSV100265772; called by muse, mutect2
- TP63 | c.903A>G p.T301= | Silent (SNP) | VAF 33/394 reads (8%) | catalogued as COSV99288595; called by muse, mutect2
- WWC2 | c.1035G>A p.L345= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs1163105671, COSV100968556; called by muse, mutect2, varscan2
- ZEB2 | c.2556A>G p.S852= | Silent (SNP) | VAF 80/302 reads (26%) | catalogued as COSV100356739; called by muse, mutect2, varscan2
- ZNF256 | c.1143C>T p.C381= | Silent (SNP) | VAF 65/218 reads (30%) | catalogued as rs992589178, COSV99991018; called by muse, mutect2, varscan2
- ZNF345 | c.1368T>C p.C456= | Silent (SNP) | VAF 282/1003 reads (28%) | catalogued as COSV100080405; called by muse, mutect2, varscan2
- ZNF493 | c.1320T>C p.T440= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV100828883; called by muse, mutect2
- ZNF644 | c.351T>C p.N117= | Silent (SNP) | VAF 53/241 reads (22%) | catalogued as COSV100494693; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823072 A>G | 5'Flank (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- DIABLO | c.-37+1397C>G | Intron (SNP) | VAF 173/393 reads (44%) | catalogued as COSV99928353; called by muse, mutect2, varscan2
- SNORD116-18 | n.53G>T | RNA (SNP) | VAF 223/849 reads (26%) | called by muse, mutect2, varscan2
